Somatic mutation profile of tumor specimen 0DIR1P from CCDI case PBBVPZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 15.2 years (5,534 days).
Specimen 0DIR1P: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 078ad4c6-66e7-4560-a88b-3981c36d0a2a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIQZN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/270dcc52-db85-4ca1-97a6-58e51ed30c72

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 2, 3'UTR 1, 5'UTR 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.176C>A p.A59E | Missense Mutation (SNP) | VAF 1001/1525 reads (66%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55568979, COSV55604554, COSV55904854; called by muse, mutect2, varscan2
- PIK3CD | c.1246T>C p.C416R | Missense Mutation (SNP) | VAF 108/279 reads (39%) | hotspot (GDC flag); SIFT tolerated (0.26); PolyPhen possibly damaging (0.88); catalogued as rs587777390, CM143040, COSV63128879; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BAX | c.87-1G>A p.X29_splice | Splice Site (SNP) | VAF 304/859 reads (35%) | catalogued as COSV53170285; called by muse, mutect2, varscan2
- DCTN1 | c.1816G>T p.V606F | Missense Mutation (SNP) | VAF 325/823 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV104422920; called by muse, mutect2, varscan2
- MCTP2 | c.1265G>A p.G422E | Missense Mutation (SNP) | VAF 282/740 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as rs761523056; called by muse, mutect2, varscan2
- PIGV | c.973G>T p.V325L | Missense Mutation (SNP) | VAF 267/710 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RPS16 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 323/801 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.208); called by muse, mutect2
- SDK1 | c.6298G>T p.D2100Y | Missense Mutation (SNP) | VAF 135/1756 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TNKS | c.2471C>A p.T824N | Missense Mutation (SNP) | VAF 240/627 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- GABRA4 | c.798G>A p.P266= | Silent (SNP) | VAF 304/1000 reads (30%) | catalogued as rs541280213, COSV51925155; called by muse, mutect2, varscan2
- NINL | c.2475G>A p.E825= | Silent (SNP) | VAF 528/934 reads (57%) | called by muse, mutect2, varscan2
- DNAJB2 | c.*43dup | 3'UTR (INS) | VAF 152/408 reads (37%) | called by mutect2, varscan2
- SCAMP1 | c.-55G>A | 5'UTR (SNP) | VAF 68/153 reads (44%) | called by muse, mutect2, varscan2
- UIMC1 | c.1949+98C>G | Intron (SNP) | VAF 150/382 reads (39%) | called by muse, mutect2, varscan2
